Gene-level copy-number profile of tumor specimen MP2PRT-PAVBXS-TTP1-A from MP2PRT case MP2PRT-PAVBXS, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.9 years (1,416 days).
Specimen MP2PRT-PAVBXS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da37e43d-f6ac-4a89-9402-40faef6a9e97.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVBXS-NB1-B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/caada04d-1a0f-4ca3-ad16-9db10ae800c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 12,169; copy number 2: 45,290; copy number 3: 120; copy number 4: 961; copy number 5: 371.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 371 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,258,885–147,517,875, 4 genes, copy number 5 (within-gene range 4–5): LINC00624, AC242426.1, OR13Z1P, Y_RNA.
- chr1:147,541,501–154,155,116, 333 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:156,308,968–156,916,434, 34 genes, copy number 5: CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4, HAPLN2, AL365181.2, BCAN, AL365181.3, AL590666.2, NES, AL590666.3, AL590666.4, CRABP2, AL590666.1, ISG20L2, RRNAD1, MRPL24, HDGF, PRCC, AL590666.5, SH2D2A, NTRK1, INSRR, PEAR1.

Autosomal genes at a single copy (total copy number 1): 9,313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
